Somatic mutation profile of tumor specimen TARGET-10-PARRMU-09A (aliquot TARGET-10-PARRMU-09A-01D) from TARGET case TARGET-10-PARRMU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.1 years (5,168 days).
Specimen TARGET-10-PARRMU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4a370a8-5174-4b83-bb3b-72c722546f60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARRMU-14A (Bone Marrow Normal), aliquot TARGET-10-PARRMU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba16fcf4-1865-4ee7-8c10-8b06f491f53a

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Frame Shift Ins 2, Silent 2, Splice Region 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.3718T>A p.C1240S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52113737; called by muse, mutect2, varscan2
- OGDHL | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs374662497; called by muse, mutect2
- PHLDB1 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); catalogued as rs535635967; called by muse, mutect2, varscan2
- RDH8 | c.424G>A p.V142I (on ENST00000651512; = p.V122I on NM_015725.4) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.267); catalogued as rs762655339, COSV50674418, COSV50675592, COSV50678474; called by muse, mutect2, varscan2
- SHROOM3 | c.3753+4C>T | Splice Region (SNP) | VAF 43/85 reads (51%) | catalogued as rs528332496; called by muse, mutect2, varscan2
- SNAPC4 | c.4120C>T p.L1374F | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs770833119; called by muse, mutect2, varscan2
- IGHV1-69D | c.353delinsCCCCCCC | In Frame Ins (INS) | VAF 27/115 reads (23%) | called by mutect2*, pindel, varscan2*
- IGHV2-26 | c.357delinsCCTCC p.*120Lfs*? | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2*, pindel, varscan2*
- ISLR2 | c.1919_1920insT p.I641Hfs*38 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- LRP1B | c.2575C>A p.Q859K | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2
- SCUBE3 | c.1212G>C p.Q404H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG17 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- UBE3C | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPLX3 | c.27G>A p.V9= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1483034922; called by muse, mutect2, varscan2
- TNFSF9 | c.465C>T p.G155= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs924891647; called by muse, mutect2, varscan2
- CD27 | c.448+35G>C | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs771715961; called by muse, varscan2
- LTO1 | c.50+333C>A | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
